Gene-level copy-number profile of tumor specimen TCGA-29-1785-01A from TCGA case TCGA-29-1785, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 55.9 years (20,417 days).
Specimen TCGA-29-1785-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.9f35633c-a588-4469-8103-108308f76323.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1785-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/87d878aa-f167-4d38-9383-401475aa9082

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 6; copy number 2: 12,620; copy number 3: 1,316; copy number 4: 42,252; copy number 5: 56; copy number 6: 2,798; copy number 7: 29; copy number 8: 43; copy number 9: 690.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1785-01A-01D-0559-01): tumor purity 0.88, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:27,798,806–27,894,752, 3 genes (within-gene range 0–2): AC005697.1, AC005697.2, LYRM9.
- chr17:27,930,177–27,930,920, 1 gene: AC005697.3.
- chr17:31,272,013–31,346,190, 5 genes: OMG, EVI2B, AC134669.1, EVI2A, AK4P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 690 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:102,503,753–145,066,685, 641 genes, copy number 9 (broad region; genes not listed).
- chr20:32,186,477–33,675,380, 49 genes, copy number 9: TSPY26P, PLAGL2, POFUT1, MIR1825, AL121897.1, KIF3B, AL121583.1, ASXL1, NOL4L, AL034550.1, AL034550.3, AL034550.2, AL133343.2, NOL4L-DT, AL133343.1, C20orf203, FO393400.1, BAK1P1, COMMD7, DNMT3B, MAPRE1, AL035071.2, AL035071.1, EFCAB8, SUN5, BPIFB2, BPIFB6, PUDPP3, BPIFB3, BPIFB4, BPIFA2, SOCS2P1, BPIFA4P, AL121901.1, BPIFA3, BPIFA1, RPL12P3, BPIFB1, BPIFB5P, BPIFB9P, CDK5RAP1, SNTA1, CBFA2T2, AL121906.2, NECAB3, C20orf144, ACTL10, ACTL10, AL121906.1.

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
